Somatic mutation profile of tumor specimen TCGA-AL-7173-01A (aliquot TCGA-AL-7173-01A-11D-2136-08) from TCGA case TCGA-AL-7173, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 72.1 years (26,326 days).
Specimen TCGA-AL-7173-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 423e3c62-3962-4693-935e-5059d0f7f8c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AL-7173-10A (Blood Derived Normal), aliquot TCGA-AL-7173-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/834241cb-85d1-4663-877d-4dbf075d51e0

The open-access MAF lists 61 somatic variants for this specimen: 48 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 10, Frame Shift Del 5, Nonsense Mutation 2, 3'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3280C>T p.H1094Y | Missense Mutation (SNP) | VAF 56/165 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913244, CM993668, COSV59256829; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADSL | c.215T>A p.I72N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV53407695; called by muse, mutect2, varscan2
- ARFRP1 | c.303C>G p.D101E | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53927413; called by muse, mutect2, varscan2
- CHRNA4 | c.580A>G p.M194V | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV64719399; called by muse, mutect2, varscan2
- COMMD2 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228870180, COSV71946471; called by muse, mutect2
- CUL3 | c.230T>C p.L77P | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52364606; called by muse, mutect2, varscan2
- CUL3 | c.5C>A p.S2* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV52364614; called by muse, mutect2, varscan2
- CUX1 | c.2833A>T p.T945S | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV52898563; called by muse, mutect2, varscan2
- CYP3A7 | c.103A>T p.K35* | Nonsense Mutation (SNP) | VAF 53/142 reads (37%) | catalogued as COSV60481472; called by muse, mutect2, varscan2
- DDX54 | c.1243T>C p.F415L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58373405; called by muse, mutect2, varscan2
- DIAPH3 | c.1033A>T p.I345F (on ENST00000400324 / NM_001042517.2; = p.I82F on NM_030932.3) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV57369882; called by muse, mutect2, varscan2
- EGF | c.670A>T p.S224C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV54478497; called by muse, mutect2, varscan2
- ESRRA | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50005206; called by muse, mutect2, varscan2
- FBXO43 | c.1486G>C p.D496H | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71053862; called by muse, mutect2, varscan2
- FCN1 | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV65662309; called by muse, mutect2, varscan2
- FETUB | c.439A>G p.I147V | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54005603; called by muse, mutect2, varscan2
- FKBP4 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50009040; called by muse, mutect2, varscan2
- FLII | c.2504T>G p.F835C | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57497851; called by muse, mutect2, varscan2
- FMC1-LUC7L2 | c.257A>T p.K86M | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV52545969; called by muse, mutect2, varscan2
- FREM1 | c.3520G>C p.V1174L | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV66523081; called by muse, mutect2, varscan2
- GTF2I | c.1201G>C p.G401R (on ENST00000573035 / NM_032999.4; = p.G360R on NM_001518.5) | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60401181; called by muse, mutect2, varscan2
- HOXA1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58029782; called by muse, mutect2, varscan2
- KEL | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62334540, COSV62334856; called by muse, mutect2, varscan2
- KERA | c.254C>G p.T85S | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as COSV57130593; called by muse, mutect2, varscan2
- MMP13 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52823622, COSV52823921; called by muse, mutect2, varscan2
- NLRP7 | c.2107A>T p.T703S (on ENST00000340844 / NM_206828.3; = p.T675S on NM_139176.3) | Missense Mutation (SNP) | VAF 90/376 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs1261412585, COSV60174216; called by muse, mutect2, varscan2
- PARVG | c.86A>T p.K29M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV63561787; called by muse, mutect2, varscan2
- PCLO | c.3043G>C p.A1015P | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs1356833412, COSV61633846; called by muse, mutect2, varscan2
- PLAU | c.199T>A p.S67T | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as COSV65641291; called by muse, mutect2, varscan2
- PLVAP | c.406A>G p.I136V | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV53084986; called by muse, mutect2, varscan2
- PRIM2 | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101263801, COSV67297700; called by muse, mutect2, varscan2
- PRKX | c.725C>G p.P242R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53323793; called by muse, mutect2, varscan2
- RGL1 | c.1807G>C p.G603R (on ENST00000360851 / NM_001297672.2; = p.G638R on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV58983339, COSV58984898; called by muse, mutect2, varscan2
- SEMA7A | c.785T>G p.V262G | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56090472; called by muse, mutect2, varscan2
- SESTD1 | c.397A>T p.T133S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.989); catalogued as COSV58931174; called by muse, mutect2, varscan2
- SPINK5 | c.2983G>C p.D995H | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56253583; called by muse, mutect2, varscan2
- ST6GAL1 | c.755del p.G252Efs*3 | Frame Shift Del (DEL) | VAF 25/135 reads (19%) | catalogued as COSV51467440; called by mutect2, pindel, varscan2
- TAF15 | c.475C>T p.H159Y (on ENST00000605844 / NM_139215.3; = p.H156Y on NM_003487.4) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1317931466; called by muse, mutect2
- WDR74 | c.60G>C p.L20F | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV53931737; called by muse, mutect2, varscan2
- ZDHHC8 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as rs532240635, COSV57710135; called by muse, mutect2, varscan2
- ZNF423 | c.2902A>G p.M968V (on ENST00000563137 / NM_001379286.1; = p.M960V on NM_015069.4) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV52187767; called by muse, mutect2, varscan2
- ZNF780A | c.446C>G p.P149R | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.443); catalogued as COSV61815377; called by muse, mutect2, varscan2
- ZPBP2 | c.281T>C p.L94P (on ENST00000348931 / NM_199321.3; = p.L72P on NM_198844.3) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62375195; called by muse, mutect2, varscan2
- ANKDD1A | c.335del p.N112Tfs*14 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | called by mutect2, pindel, varscan2
- CDK8 | c.1243_1246delinsAA p.G415Nfs*114 | Frame Shift Del (DEL) | VAF 11/90 reads (12%) | called by pindel, varscan2*
- ITGA1 | c.1481del p.L494* | Frame Shift Del (DEL) | VAF 26/136 reads (19%) | called by mutect2, pindel, varscan2
- LARS1 | c.207del p.K69Nfs*6 (on ENST00000394434 / NM_020117.11; = p.K69Nfs*9 on NM_016460.3) | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- PPIL2 | c.561G>C p.E187D | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.777); called by muse, mutect2
- CPNE6 | c.1146G>A p.P382= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs778192102, COSV53743123; called by muse, mutect2, varscan2
- MAGI2 | c.828G>T p.V276= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV62644029; called by muse, mutect2, varscan2
- NEXMIF | c.3300G>A p.E1100= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as COSV50030151; called by muse, mutect2
- PEAK1 | c.5050C>T p.L1684= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV56934980; called by muse, mutect2, varscan2
- PRIM2 | c.576G>T p.L192= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV67297697; called by muse, mutect2, varscan2
- RERE | c.4530C>A p.P1510= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs778213222, COSV61941733; called by muse, mutect2, varscan2
- SH2B3 | c.1164G>A p.V388= | Silent (SNP) | VAF 25/150 reads (17%) | catalogued as COSV57983156; called by muse, varscan2
- SLCO2B1 | c.1998C>T p.F666= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as rs192050675; called by muse, mutect2, varscan2
- TRAPPC12 | c.2079G>A p.V693= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as COSV60847356; called by muse, mutect2, varscan2
- TSPAN2 | c.432C>T p.T144= | Silent (SNP) | VAF 38/155 reads (25%) | catalogued as COSV65689965; called by muse, mutect2, varscan2
- CPLANE1 | c.*2969C>G | 3'UTR (SNP) | VAF 5/25 reads (20%) | catalogued as COSV57059396; called by muse, mutect2, varscan2
- HMGN2P46 | n.819G>A | RNA (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- LRRC23 | c.*190A>C | 3'UTR (SNP) | VAF 62/159 reads (39%) | catalogued as COSV99145329; called by muse, mutect2, varscan2
